Gene-level copy-number profile of tumor specimen C3L-08429-02 from CPTAC case C3L-08429, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 61.5 years (22,471 days).
Specimen C3L-08429-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b6d2c04b-ab5c-47d9-a459-baa423ea5b14.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-08429-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate.
https://portal.gdc.cancer.gov/files/0ab8af69-7d35-4d89-b096-dd7fc58e464e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 629; copy number 1: 656; copy number 2: 9,897; copy number 3: 15,511; copy number 4: 20,268; copy number 5: 5,741; copy number 6: 3,633; copy number 7: 1,418; copy number 8: 404; copy number 9: 608; copy number 10: 70; copy number 11: 41; copy number 12: 8; copy number 13: 12; copy number 14: 3.

Homozygous deletions (total copy number 0; autosomes only): 80 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:157,876,702–158,136,154, 8 genes (within-gene range 0–2): UPP2, AC013731.1, RNU6-436P, AC091488.1, MTA3P1, RNU6-932P, PTP4A1P1, UPP2-IT1.
- chr2:165,087,526–165,204,050, 1 gene (within-gene range 0–4): SCN3A.
- chr2:165,285,253–165,286,048, 1 gene (within-gene range 0–4): MAPRE1P3.
- chr2:186,162,949–186,163,245, 1 gene: AC104058.1.
- chr2:186,486,253–186,695,287, 4 genes (within-gene range 0–3): ZC3H15, DPRXP1, ITGAV, AC017101.1.
- chr4:69,280,475–69,423,164, 7 genes (within-gene range 0–4): UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P.
- chr5:59,528,861–59,703,703, 2 genes (within-gene range 0–2): NDUFB4P2, MIR582.
- chr5:60,304,047–60,460,739, 3 genes (within-gene range 0–2): RNU6-806P, AC109486.1, SETP21.
- chr7:90,119,299–90,164,829, 3 genes (within-gene range 0–1): AC004969.1, DPY19L2P4, STEAP1.
- chr9:9,442,060–9,442,380, 1 gene (within-gene range 0–7): RN7SL5P.
- chr10:74,151,202–74,709,963, 9 genes: ADK, TIMM9P1, RPSAP6, RAB5CP1, AC022540.1, MRPL35P3, Y_RNA, NDUFA8P1, POLR3DP1.
- chr10:75,552,458–75,552,553, 1 gene (within-gene range 0–3): MIR606.
- chr10:75,642,476–75,643,106, 1 gene (within-gene range 0–3): AL589863.1.
- chr13:59,665,583–60,163,928, 4 genes (within-gene range 0–3): DIAPH3, DIAPH3-AS1, RN7SL375P, DIAPH3-AS2.
- chr14:36,647,083–37,172,606, 7 genes (within-gene range 0–4): AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1.
- chr14:45,274,359–45,503,140, 5 genes: RNU6-552P, DNAJC19P9, AL162632.3, AL162632.1, AL162632.2.
- chr14:67,659,820–67,816,590, 9 genes (within-gene range 0–2): AL049779.1, RDH11, RDH12, RN7SL369P, RPL21P9, ZFYVE26, AL049779.3, RN7SL213P, AL049779.2.
- chr20:14,933,843–15,022,958, 3 genes (within-gene range 0–2): AL138808.1, RNU6-1159P, RNU6-115P.
- chr22:28,883,572–29,191,808, 8 genes: ZNRF3, ZNRF3-IT1, ZNRF3-AS1, C22orf31, KREMEN1, AL021393.1, RNU6-810P, RNU6-1219P.
- chr22:46,360,834–46,537,620, 2 genes (within-gene range 0–3): CELSR1, AL031597.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 742 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:234,527,887–234,760,056, 12 genes, copy number 13: LINC01354, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, LINC01132, PP2672.
- chr2:100,993,676–101,308,701, 8 genes, copy number 12 (within-gene range 6–12): AC016738.1, RPL31, TBC1D8, BBIP1P1, TBC1D8-AS1, CNOT11, RNF149, SNORD89.
- chr8:120,052,180–121,994,185, 14 genes, copy number 11 (within-gene range 7–11): AC091563.1, COL14A1, MRPL13, MTBP, SNTB1, NCAPGP1, AC104958.1, AC104958.2, AC068413.1, AC011626.1, RPL35AP19, HAS2, HAS2-AS1, LINC02855.
- chr9:4,386,410–6,727,438, 70 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).
- chr12:122,749,481–122,827,528, 4 genes, copy number 9: AC026333.2, DENR, Y_RNA, CCDC62.
- chr12:124,776,856–125,143,333, 11 genes, copy number 9 (within-gene range 5–9): SCARB1, AC073593.2, RNU6-927P, UBC, MIR5188, RPL22P19, DHX37, BRI3BP, THRIL, AC122688.1, AACS.
- chr14:18,333,726–18,419,273, 4 genes, copy number 9: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr19:41,449,520–41,881,372, 27 genes, copy number 11: PCAT19, AC243960.2, PLEKHA3P1, AC243960.3, LINC01480, AC243960.1, CEACAM21, AC243960.10, CEACAMP3, DNAJC19P2, CEACAM4, DNAJC19P3, AC243960.5, AC243960.4, CEACAM7, CEACAM5, AC243967.1, CEACAM6, AC243967.2, CEACAM3, HNRNPA1P52, AC243967.3, LYPD4, DMRTC2, RPS19, MIR6797, CD79A.
- chr20:33,007,704–33,994,357, 34 genes, copy number 9 (within-gene range 7–9): BPIFB2, BPIFB6, PUDPP3, BPIFB3, BPIFB4, BPIFA2, SOCS2P1, BPIFA4P, AL121901.1, BPIFA3, BPIFA1, RPL12P3, BPIFB1, BPIFB5P, BPIFB9P, CDK5RAP1, SNTA1, CBFA2T2, AL121906.2, NECAB3, C20orf144, ACTL10, ACTL10, AL121906.1, E2F1, PXMP4, AL050349.1, ZNF341, RPL31P2, ZNF341-AS1, CHMP4B, TPM3P2, PIGPP3, RALY-AS1.
- chr20:34,088,309–41,712,600, 198 genes, copy number 9–14 (within-gene range 7–14) (broad region; genes not listed).
- chr20:43,189,998–51,905,030, 254 genes, copy number 9 (broad region; genes not listed).
- chr20:61,953,469–63,891,545, 106 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 308. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
